Gene-level copy-number profile of tumor specimen TCGA-XE-AANZ-01A from TCGA case TCGA-XE-AANZ, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 32.3 years (11,795 days).
Specimen TCGA-XE-AANZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 995a38ec-f84e-434e-afcd-e983b3858293.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-XE-AANZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/bf6b7e6a-3343-4a4d-9075-934529fdf7a1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 5,460; copy number 2: 33,800; copy number 3: 17,938; copy number 4: 1,712; copy number 5: 2.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:109,313,571–109,313,625, 1 gene (within-gene range 0–2): MIR4266.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:13,095,305–13,120,807, 2 genes, copy number 5: ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 2,614. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
